CCDI case PBBPYS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2af762bb-74fd-4bc2-ba00-e7e77b3de38c

Demographics
Sex at birth: male; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.8 years (2,858 days).

Biospecimens (3 samples)
- Sample 0DELJ5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DELJT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DELKB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
